Somatic mutation profile of cancer-model specimen HCM-CSHL-0875-C67-85B (3D Organoid, passage 4; aliquot HCM-CSHL-0875-C67-85B-01D-A88H-36), derived from the primary tumor of HCMI case HCM-CSHL-0875-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0875-C67-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fbc9a8a-fdef-4878-b81e-59e8b454303b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0875-C67-10A (Blood Derived Normal), aliquot HCM-CSHL-0875-C67-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f29ecde3-833b-413b-8e12-b61ce6f76351

The open-access MAF lists 58 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 12, Frame Shift Del 3, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD2B | c.3700A>G p.T1234A | Missense Mutation (SNP) | VAF 161/365 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.779); catalogued as rs1236715673; called by muse, mutect2, varscan2
- C19orf54 | c.352T>C p.F118L | Missense Mutation (SNP) | VAF 289/641 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as rs887023616; called by muse, mutect2, varscan2
- CLCA4 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 108/218 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1380123797, COSV55367727; called by muse, mutect2, varscan2
- CSMD3 | c.7777C>A p.R2593S (on ENST00000297405 / NM_001363185.1; = p.R2489S on NM_052900.3) | Missense Mutation (SNP) | VAF 495/751 reads (66%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV52164475, COSV52212859; called by muse, mutect2, varscan2
- CYP2A6 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 259/526 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs145036049; called by muse, mutect2, varscan2
- EP300 | c.4344C>A p.F1448L | Missense Mutation (SNP) | VAF 206/416 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1301481387; called by muse, mutect2, varscan2
- FIBCD1 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 359/759 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs934840504; called by muse, mutect2, varscan2
- FTCD | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 285/614 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760263005, COSV52429534; called by muse, mutect2, varscan2
- LAMA2 | c.7346T>C p.I2449T | Missense Mutation (SNP) | VAF 116/228 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs1156828795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MKRN3 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 281/607 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1430827944; called by muse, mutect2, varscan2
- MYORG | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 273/593 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1006112382; called by muse, mutect2, varscan2
- NLRP9 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 247/550 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs751248353, COSV100242830; called by muse, mutect2, varscan2
- OR10G4 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 228/764 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199564594; called by muse, varscan2
- SF1 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 282/549 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs200685412; called by muse, mutect2, varscan2
- TRIM54 | c.812T>C p.M271T (on ENST00000380075 / NM_187841.3; = p.M313T on NM_032546.4) | Missense Mutation (SNP) | VAF 265/531 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs78879946; called by muse, mutect2, varscan2
- ABCA7 | c.3398G>A p.G1133E | Missense Mutation (SNP) | VAF 183/367 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADAM12 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 235/529 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AOC1 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 18/626 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.209); called by muse, mutect2
- B4GALT3 | c.917T>A p.L306H | Missense Mutation (SNP) | VAF 179/401 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FAM189B | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 368/799 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FRY | c.4877A>C p.Y1626S | Missense Mutation (SNP) | VAF 232/504 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- GPR32 | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 22/560 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.333); called by muse, mutect2
- HIVEP3 | c.3334G>A p.G1112R | Missense Mutation (SNP) | VAF 348/775 reads (45%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- HYDIN | c.7474C>T p.H2492Y | Missense Mutation (SNP) | VAF 342/725 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- KMT2D | c.3792_3808del p.P1265Tfs*15 | Frame Shift Del (DEL) | VAF 304/666 reads (46%) | called by mutect2, pindel, varscan2
- KMT2D | c.10_16del p.Q4Wfs*124 | Frame Shift Del (DEL) | VAF 224/501 reads (45%) | called by mutect2, pindel, varscan2
- NEURL1B | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 22/839 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0.042); called by muse, mutect2
- OR10G4 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 236/546 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- OR51B5 | c.353A>C p.Y118S | Missense Mutation (SNP) | VAF 58/337 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by mutect2, varscan2
- OR52E4 | c.22C>A p.H8N | Missense Mutation (SNP) | VAF 103/228 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR8H3 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 178/375 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR8J3 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCMT1 | c.18_26dup p.S9_G11dup | In Frame Ins (INS) | VAF 236/516 reads (46%) | called by mutect2, varscan2
- SETBP1 | c.2168T>C p.I723T | Missense Mutation (SNP) | VAF 255/534 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIM1 | c.1589A>G p.E530G | Missense Mutation (SNP) | VAF 23/359 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLC38A9 | c.833C>G p.A278G | Missense Mutation (SNP) | VAF 197/526 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SLC9A1 | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 157/300 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SPATA31A7 | c.470C>G p.P157R | Missense Mutation (SNP) | VAF 171/689 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPOCK2 | c.1009T>A p.C337S | Missense Mutation (SNP) | VAF 222/485 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- STAT5B | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 313/667 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- TAZ | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 242/475 reads (51%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- THSD7A | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 216/483 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- TMEM108 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 193/399 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM198 | c.422del p.Y141Sfs*38 | Frame Shift Del (DEL) | VAF 388/954 reads (41%) | called by mutect2, pindel, varscan2
- TXLNA | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 302/631 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- ALKBH2 | c.501C>T p.H167= | Silent (SNP) | VAF 174/369 reads (47%) | called by muse, mutect2, varscan2
- BMERB1 | c.210G>A p.R70= | Silent (SNP) | VAF 165/329 reads (50%) | called by muse, mutect2, varscan2
- DHRS1 | c.63T>A p.R21= | Silent (SNP) | VAF 351/693 reads (51%) | called by muse, mutect2, varscan2
- HK1 | c.1494G>A p.G498= | Silent (SNP) | VAF 243/536 reads (45%) | called by muse, mutect2, varscan2
- INPP5K | c.897C>A p.G299= | Silent (SNP) | VAF 227/476 reads (48%) | called by muse, mutect2, varscan2
- MUC16 | c.41769G>A p.E13923= | Silent (SNP) | VAF 182/368 reads (49%) | catalogued as COSV66692902; called by muse, mutect2, varscan2
- PHACTR2 | c.777G>A p.G259= | Silent (SNP) | VAF 233/496 reads (47%) | called by muse, mutect2, varscan2
- PRSS12 | c.1185C>T p.S395= | Silent (SNP) | VAF 170/473 reads (36%) | called by muse, mutect2, varscan2
- SMS | c.57T>G p.G19= | Silent (SNP) | VAF 140/320 reads (44%) | called by muse, mutect2, varscan2
- ZAP70 | c.987G>A p.K329= | Silent (SNP) | VAF 300/645 reads (47%) | catalogued as COSV53855934; called by muse, mutect2, varscan2
- ZNF716 | c.384C>T p.C128= | Silent (SNP) | VAF 64/139 reads (46%) | catalogued as COSV101348767; called by muse, mutect2, varscan2
- ZSCAN30 | c.204G>A p.R68= | Silent (SNP) | VAF 344/648 reads (53%) | called by muse, mutect2
- AL353804.4 | chrX:73821415 G>T | 3'Flank (SNP) | VAF 83/183 reads (45%) | called by muse, mutect2, varscan2
